Somatic mutation profile of tumor specimen TARGET-20-PASJTM-09A (aliquot TARGET-20-PASJTM-09A-02D) from TARGET case TARGET-20-PASJTM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (901 days).
Specimen TARGET-20-PASJTM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 191a8824-6dea-44f9-8578-ae8ea0a3a678.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASJTM-14A (Bone Marrow Normal), aliquot TARGET-20-PASJTM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21521699-2509-470b-ae29-d335fd2d1745

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs28941778, CM003970, CM127190, CM910413, COSV60066459, COSV60067963; ClinVar: pathogenic; called by muse, varscan2
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, varscan2
